Gene-level copy-number profile of tumor specimen HTMCP-03-06-02176-01A from CGCI case HTMCP-03-06-02176, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8e82688-a486-49ef-bd12-a1248ba5d56d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02176-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,401 have no estimate.
https://portal.gdc.cancer.gov/files/08557db1-e226-4e90-854d-94939b4555ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 223; copy number 2: 10,754; copy number 3: 25,327; copy number 4: 13,095; copy number 5: 5,853; copy number 6: 2,561; copy number 7: 289; copy number 8: 52; copy number 10: 52; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,312,846–7,319,951, 1 gene (within-gene range 0–1): DEFB109B.
- chr8:7,341,826–7,342,942, 1 gene (within-gene range 0–1): AC130360.1.
- chr8:12,194,467–12,196,280, 1 gene: AC145124.1.
- chr8:12,362,019–12,400,366, 4 genes: FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr15:34,415,450–34,588,503, 7 genes (within-gene range 0–3): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 386 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,847,174–93,848,939, 1 gene, copy number 7: AL049796.1.
- chr3:183,697,797–183,888,449, 7 genes, copy number 7: YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448.
- chr3:189,956,728–190,122,437, 2 genes, copy number 7 (within-gene range 6–7): P3H2, MTAPP2.
- chr3:196,214,222–198,123,232, 73 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:38,269,491–38,296,233, 5 genes, copy number 10 (within-gene range 6–10): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB.
- chr8:7,836,436–8,049,267, 17 genes, copy number 8: DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:12,095,176–12,194,133, 10 genes, copy number 8–13: DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1.
- chr8:101,686,542–102,124,907, 1 gene, copy number 7 (within-gene range 4–7): NCALD.
- chr8:101,871,830–103,501,895, 48 genes, copy number 7 (within-gene range 6–7): PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr8:123,178,960–123,470,028, 20 genes, copy number 8: FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4.
- chr8:124,306,189–125,438,403, 25 genes, copy number 7–8: TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1.
- chr8:143,080,457–145,066,685, 129 genes, copy number 7 (broad region; genes not listed).
- chr11:107,790,991–107,928,293, 1 gene, copy number 7 (within-gene range 5–7): SLC35F2.
- chr14:22,123,318–22,490,553, 46 genes, copy number 10: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.

Autosomal genes at a single copy (total copy number 1): 223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
